Gene-level copy-number profile of tumor specimen HTMCP-01-16-00783-01A from CGCI case HTMCP-01-16-00783, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 45.1 years (16,455 days).
Specimen HTMCP-01-16-00783-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 08767e2b-3dfd-4444-9e99-cf53bd916ee3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-16-00783-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/5b16e571-9217-4778-889b-dfd37d1d5a17

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 2,081; copy number 2: 48,600; copy number 3: 7,131; copy number 4: 134; copy number 5: 672; copy number 6: 218; copy number 7: 54.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,887,294–29,934,286, 8 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 665 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,913,982–89,916,052, 1 gene, copy number 6: IGKV1D-33.
- chr7:75,769,533–110,534,757, 619 genes, copy number 5 (broad region; genes not listed).
- chr8:8,086,022–8,089,089, 2 genes, copy number 5: AC105233.2, MIR548I3.
- chr9:64,810,865–64,836,341, 2 genes, copy number 5: BNIP3P4, AL359955.1.
- chr12:14,356,842–14,502,935, 2 genes, copy number 5: RPL30P11, ATF7IP.
- chr13:81,689,911–88,978,785, 39 genes, copy number 6: PTMAP5, AL445255.1, GYG1P2, AL512782.1, RNU6-67P, SLITRK1, AL355481.1, VENTXP2, UBE2D3P4, MTND4P1, MTND5P3, LINC00333, LINC00375, LINC00351, SLITRK6, AL162373.1, MOB1AP1, AL354994.1, DDX6P2, TXNL1P1, LINC00430, UBBP5, LIN28AP2, AL360267.2, AL360267.1, MIR4500HG, AL355578.1, MIR4500, SLITRK5, AL445647.2, LINC00397, AL445647.1, TET1P1, LINC00373, RPL29P29, LINC00433, AL445984.2, LINC00560, GRPEL2P1.

Autosomal genes at a single copy (total copy number 1): 1,053. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
